Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KO, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KO-01A (Primary Tumor).

Pathology report

Date of tumor procurement

Date of report

Histologic diagnosis

High grade muscle invasive urothelial cell carcinoma + CIS. T3aN0Mx

Anatomic site and laterality

Right dorsolateral bladder wall

Tumor size

2.5cm diameter

Lymph node status

A total of 18 lymph nodes all without tumor localization

ICD-O-3

Carcinomas, urothelial NOS
C67.4 8120/3

Site: Bladder, posterior wall
Bladder, overlapping lesion
C67.4
C67.8

Q20 1/29/14

Source: NCI Genomic Data Commons file 78e5a967-9479-4fca-8559-aee5730a288c (TCGA-2F-A9KO.FA1D30C7-E486-48DD-989F-E774B42EA1B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).